Surgical pathology report (de-identified scan), TCGA case TCGA-VD-AA8O, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-AA8O-01A (Primary Tumor).

[page 1 of 3]
Department of Pathology			HISTOPATHOLOGY		
Surname	Lab No		Clinical Consultant & Location		
Forename(s)	DOB/Age	Sex			
Unit No	Request Date				

This Copy For:

SPECIMEN

LEFT ENUCLEATION (GLOBE), DIAGNOSTIC, PROGNOSTIC

CLINICAL DETAILS

See diagram.

MACROSCOPIC DESCRIPTION

A fresh, intact, left gloe.

Dimensions: Axial 25.5mm, Horizontal 24mm, Vertical 24mm

Cornea: Horizontal 12mm, Vertical 11.5mm

Optic nerve
Length 1mm, Diameter 4mm

On trans-illumination, a large shadow is seen on the medium side approx 22mm

Plane of section: horizontal

Intraocular description:

On opening, a solitary dome shaped pigmented choroidal mass is found.

Query: ciliary body involvement!

Tumour size

LBD 13.5mm, Height 13mm

MICROSCOPY

Histologically, the enucleated eye demonstrates a normal anterior segment with an unremarkable cornea, a deep anterior chamber and open angles. The iris leaves are unremarkable. The ciliary muscles are moderately atrophic. There is mild hyalinisation of the ciliary processes. The lens shows advanced cataractous changes.

At the level of the equator in the posterior segment, a choroidal melanoma can be seen. This is dome-shaped with a large accompanying exudative retinal detachment. The retina

*ICD-O 3
Melanoma, epithelioid & spindle cell
mixed 8770/3
Site: Choroid 069.3
10/3/14*

Reported:

Pathologist:

Electronically Verified:

[page 2 of 3]
Department of Pathology

Page 2 of 3

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

overlying the tumour is atrophic with degenerative changes. Focally, at the apex of the tumour, there is retinal invasion.

The tumour is heavily pigmented and consists of a mixture of cells, both epithelioid and spindle cells, with a dominance of the former. The melanoma cells are immunoreactive for MelanA, CD117 and HSP-27 (score 1).

The number of mitoses is approx. 2/40 high power fields.

The microvasculature of the melanoma is prominent, and closed loops are present in the tissue planes evaluated. Numerous "vascular lakes" can be observed; in these tumour cells can be seen located within the lumen. The lymphocytic infiltrate within tumour is moderate. Macrophages are scattered throughout the tumour in a mild density.

There is no evidence of scleral invasion and there is no clear evidence of extraocular growth.

The optic nerve is cut very short but is tumour free, and demonstrates mild atrophic changes. The examined vortex veins are free of tumour.

FINAL DIAGNOSIS

Choroidal melanoma of epithelioid cell type.

COMMENT

Molecular genetic examination of DNA extracted from the tumour cells will be performed using multiplex-ligation dependent probe amplification (MLPA), looking at chromosomes 1, 3, 6 and 8. A supplementary report will follow as soon as these investigations are complete.

SUPPLEMENTARY REPORT (MLPA)

In the meantime, molecular genetic analysis of tumour DNA extracted from the fresh uveal melanoma tissue was performed using the technique termed multiplex ligation-dependent

Reported:

Pathologist: [REDACTED]

Electronically Verified: [REDACTED]

[page 3 of 3]
Department of Pathology

Page 3 of 3

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

probe amplification (MLPA). These investigations were performed in the

The kit P027 from [REDACTED] which examines for gains or losses in 31 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using [REDACTED] and the quality assessed using multiplex-PCR prior to the MLPA reaction.

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

The results of the sequence analysis of the MLPA products is printed on a separate report. In summary, sequence analysis demonstrated:

Loss of chromosome 1p,
Monosomy 3,
Gain of chromosome 6p
and borderline gains in chromosome 8q.

Taken together, these molecular data would place the patient in the 'high' risk group with respect to the development of metastatic melanoma. Consideration of clinical features of the tumour is, however, also required.

ADDITIONAL SUPPLEMENTARY REPORT (MSA)

For quality assurance purposes, MSA was also performed on this sample: Loss of heterozygosity (LOH) for 4/4 of the examined loci on chromosome 3p and for 4/4 of the examined loci on chromosome 3q.

According to published criteria, these alterations amount to "monosomy 3".

These molecular data are in complete agreement with the MLPA results, and would place the patient in the high risk group; however, require correlation with the clinical and morphological data for metastatic risk assessment.

Reported:

Pathologist: [REDACTED]

Electronically Verified: [REDACTED]

Reviewed Initials	Date Reviewed 12/19/13	

Source: NCI Genomic Data Commons file 6c5e00f1-fe38-40fd-a2b1-41048ea1bb94 (TCGA-VD-AA8O.47696668-32A5-44CB-8141-3613B07CC231.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).